Somatic mutation profile of tumor specimen TCGA-2F-A9KP-01A (aliquot TCGA-2F-A9KP-01A-11D-A38G-08) from TCGA case TCGA-2F-A9KP, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 66.9 years (24,428 days).
Specimen TCGA-2F-A9KP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec8ad234-82be-43bc-90bb-b1368961f850.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2F-A9KP-10A (Blood Derived Normal), aliquot TCGA-2F-A9KP-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/97413baa-7696-4da4-be70-f34f53165620

The open-access MAF lists 144 somatic variants for this specimen: 106 protein-altering or splice-affecting, 37 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 88, Silent 37, Nonsense Mutation 7, Frame Shift Del 4, Splice Site 3, Frame Shift Ins 3, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 1853/1862 reads (100%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen benign (0.103); catalogued as rs1057519862, COSV54062926; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 54/70 reads (77%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACHE | c.1429C>T p.P477S | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as rs1226438649, COSV53815016, COSV53821033; called by muse, mutect2, varscan2
- ADGRG5 | c.280C>G p.L94V | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV61084361; called by muse, mutect2, varscan2
- AMPH | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV57754680; called by muse, mutect2
- ANKRD30A | c.2844G>T p.M948I (on ENST00000611781; = p.M892I on NM_052997.2) | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1302676739, COSV64605965, COSV64619278; called by muse, mutect2, varscan2
- ARHGEF25 | c.466A>G p.K156E | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs894952649, COSV54090031; called by muse, mutect2, varscan2
- ARHGEF25 | c.467A>C p.K156T | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs947921217, COSV54090047; called by muse, mutect2, varscan2
- ARID1A | c.4101+1G>A p.X1367_splice | Splice Site (SNP) | VAF 134/204 reads (66%) | catalogued as COSV61375328, COSV61387522; called by muse, mutect2, varscan2
- ARID2 | c.1318G>T p.E440* | Nonsense Mutation (SNP) | VAF 20/61 reads (33%) | catalogued as COSV100537141; called by muse, mutect2, varscan2
- ART1 | c.908C>G p.S303C | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV51704151, COSV51706806; called by muse, mutect2, varscan2
- ASCC3 | c.4719G>C p.L1573F | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.635); catalogued as COSV64980022; called by muse, mutect2, varscan2
- ATP10D | c.3240G>A p.Q1080= | Splice Region (SNP) | VAF 23/61 reads (38%) | catalogued as COSV56712472; called by muse, mutect2, varscan2
- ATP8B2 | c.146C>T p.A49V (on ENST00000672630; = p.A16V on NM_001005855.2) | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368910102; called by muse, mutect2, varscan2
- BAK1 | c.574C>G p.L192V | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV62349890; called by muse, mutect2, varscan2
- C10orf71 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV60512078; called by muse, mutect2, varscan2
- C3AR1 | c.812G>A p.S271N | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV50823346; called by muse, mutect2, varscan2
- CCDC191 | c.2581G>A p.E861K | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55675684; called by muse, mutect2, varscan2
- CDC5L | c.2009A>G p.Y670C | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV65176876; called by muse, mutect2, varscan2
- CDK15 | c.736G>A p.A246T (on ENST00000652192 / NM_001366386.2; = p.A195T on NM_139158.2) | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV53637819, COSV99643555; called by muse, mutect2, varscan2
- CENPE | c.3118G>C p.E1040Q | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.1); catalogued as COSV54388739, COSV99478434; called by muse, mutect2, varscan2
- CHD5 | c.3407G>A p.R1136H | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs1162494442, COSV52418865; called by muse, mutect2, varscan2
- CHRND | c.1349G>A p.R450K | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV51329167; called by muse, mutect2, varscan2
- COL4A4 | c.4873G>C p.D1625H | Missense Mutation (SNP) | VAF 36/60 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61631178, COSV61635950; called by muse, mutect2, varscan2
- COL5A2 | c.1994G>C p.R665T | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.535); catalogued as COSV66412828, COSV66414248; called by muse, mutect2, varscan2
- DCAF4L2 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100150917, COSV60481430; called by muse, mutect2, varscan2
- DCAF8L1 | c.1563A>T p.L521F | Missense Mutation (SNP) | VAF 42/48 reads (88%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.81); catalogued as COSV71595499; called by muse, mutect2, varscan2
- DDHD1 | c.967C>T p.R323W (on ENST00000323669; = p.R520W on NM_030637.3) | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1244136650, COSV60362211; called by muse, mutect2, varscan2
- DGKA | c.1102-1G>A p.X368_splice | Splice Site (SNP) | VAF 53/238 reads (22%) | catalogued as COSV59388392; called by muse, mutect2, varscan2
- DLGAP5 | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV55965027; called by muse, mutect2, varscan2
- DNAH7 | c.2224G>A p.E742K | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV56782234; called by muse, mutect2, varscan2
- ERC1 | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773843924, COSV61698092; called by muse, mutect2, varscan2
- ERCC6 | c.50G>A p.C17Y | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1196819313, COSV63393830; called by muse, mutect2, varscan2
- EYA1 | c.898G>C p.D300H | Missense Mutation (SNP) | VAF 96/209 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV58172619; called by muse, mutect2, varscan2
- FAM110C | c.750C>G p.S250R | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59656474; called by muse, mutect2, varscan2
- FOLR3 | c.565T>A p.C189S | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61530802; called by muse, mutect2, varscan2
- FOXL1 | c.924C>G p.F308L | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV57215194; called by muse, mutect2, varscan2
- FREM1 | c.6073G>C p.E2025Q | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.042); catalogued as COSV66529028; called by muse, mutect2, varscan2
- FXYD6 | c.149C>T p.S50L | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.77); PolyPhen benign (0.043); catalogued as rs571985984, COSV52805106; called by muse, mutect2, varscan2
- GAK | c.319A>G p.I107V | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as rs138465573; called by muse, mutect2, varscan2
- GRM7 | c.455G>T p.G152V | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63166369; called by muse, mutect2, varscan2
- GRXCR1 | c.382C>T p.Q128* | Nonsense Mutation (SNP) | VAF 19/95 reads (20%) | catalogued as rs771784846, COSV101295762; called by muse, mutect2, varscan2
- H2AC4 | c.232C>A p.R78S | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV52519792; called by muse, mutect2, varscan2
- HOMEZ | c.1216G>A p.D406N | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62537695; called by muse, mutect2, varscan2
- HTATSF1 | c.2257G>A p.D753N | Missense Mutation (SNP) | VAF 39/54 reads (72%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.068); catalogued as rs368856206, COSV54477703; called by muse, mutect2, varscan2
- ITGB3 | c.2351C>T p.T784M | Missense Mutation (SNP) | VAF 26/32 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs367659742; called by muse, mutect2, varscan2
- KCNQ5 | c.909G>T p.W303C | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59679554; called by muse, mutect2, varscan2
- KDM6A | c.823_824dup p.L277Pfs*49 | Frame Shift Ins (INS) | VAF 38/70 reads (54%) | catalogued as COSV65046423; called by mutect2, pindel, varscan2
- KHDC1 | c.646G>A p.V216I (on ENST00000370384 / NM_001251874.2; = p.V143I on NM_030568.5) | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.045); catalogued as rs373674170; called by muse, mutect2, varscan2
- KIF4A | c.383A>G p.K128R | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1248911890, COSV65545445; called by muse, mutect2, varscan2
- LMTK2 | c.454C>T p.L152F | Missense Mutation (SNP) | VAF 61/144 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV52002868; called by muse, mutect2, varscan2
- LSAMP | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0.034); catalogued as rs781746510, COSV61308218; called by muse, mutect2, varscan2
- LTBP1 | c.1510G>A p.D504N (on ENST00000404816 / NM_206943.4; = p.D178N on NM_000627.4) | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as rs1449446126, COSV100617914, COSV63196653; called by muse, mutect2, varscan2
- MDGA2 | c.3070C>G p.R1024G (on ENST00000399232 / NM_001113498.2; = p.R726G on NM_182830.4) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV62109822; called by muse, mutect2, varscan2
- MED12 | c.597G>C p.Q199H | Missense Mutation (SNP) | VAF 37/50 reads (74%) | SIFT tolerated (0.4); PolyPhen benign (0.18); catalogued as COSV61353782; called by muse, mutect2, varscan2
- MED24 | c.1643G>C p.R548P | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.608); catalogued as COSV62420565; called by muse, mutect2, varscan2
- MRPS6 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.212); catalogued as COSV62972921; called by muse, mutect2, varscan2
- MYO1E | c.2181G>C p.L727F | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT tolerated (0.66); PolyPhen benign (0.029); catalogued as COSV55694219; called by muse, mutect2, varscan2
- NARS2 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1230081561, COSV55255182; called by muse, mutect2, varscan2
- NKX2-2 | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV101010636, COSV65819196; called by muse, mutect2, varscan2
- NOP14 | c.628C>G p.Q210E | Missense Mutation (SNP) | VAF 66/181 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.212); catalogued as COSV58627495; called by muse, mutect2, varscan2
- OGFRL1 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV64972462; called by muse, mutect2
- OR4P4 | c.122T>C p.L41S | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as rs1448219393, COSV58923395; called by muse, mutect2, varscan2
- OR6M1 | c.34del p.L12* | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | catalogued as COSV100484063; called by mutect2, pindel, varscan2
- PCLO | c.14959G>A p.E4987K | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as COSV61616227; called by muse, mutect2, varscan2
- PCLO | c.5162A>T p.H1721L | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.918); catalogued as COSV61661273; called by muse, mutect2
- PCNX4 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV58307557; called by muse, mutect2, varscan2
- PDCD11 | c.1497C>G p.I499M | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.426); catalogued as rs1051853046, COSV63935138; called by muse, mutect2, varscan2
- PITPNC1 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 44/50 reads (88%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.458); catalogued as COSV55457346; called by muse, mutect2, varscan2
- PNLIPRP2 | c.1375G>C p.E459Q (on ENST00000611850; = p.E460Q on NM_005396.5) | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as COSV53946314; called by muse, mutect2, varscan2
- POLE | c.254A>G p.Y85C | Missense Mutation (SNP) | VAF 47/144 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs1565981016, COSV57689085; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRKCD | c.846C>G p.I282M | Missense Mutation (SNP) | VAF 41/68 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV57851068; called by muse, mutect2, varscan2
- PTBP3 | c.1105-2A>C p.X369_splice | Splice Site (SNP) | VAF 28/41 reads (68%) | catalogued as COSV57586820; called by muse, mutect2, varscan2
- RABGAP1 | c.1221G>A p.M407I | Missense Mutation (SNP) | VAF 128/166 reads (77%) | SIFT tolerated (0.07); PolyPhen benign (0.315); catalogued as rs769879519, COSV65395569; called by muse, mutect2, varscan2
- RADIL | c.1784G>A p.R595H | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs559606209, COSV68199263; called by muse, mutect2, varscan2
- RIMBP2 | c.2668G>A p.D890N | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55480717, COSV55482777; called by muse, mutect2, varscan2
- RPF1 | c.742C>G p.L248V | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs575850309, COSV65706041; called by muse, mutect2, varscan2
- RSPO2 | c.454G>T p.E152* | Nonsense Mutation (SNP) | VAF 47/109 reads (43%) | catalogued as rs140125293, COSV99410526; called by muse, mutect2, varscan2
- RUNX3 | c.745G>A p.D249N | Missense Mutation (SNP) | VAF 40/191 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as rs200276750, COSV58245673; called by muse, mutect2, varscan2
- RYR2 | c.9342G>T p.Q3114H | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.73); catalogued as rs1411627363, COSV100773178; called by muse, mutect2, varscan2
- S1PR1 | c.213G>A p.W71* | Nonsense Mutation (SNP) | VAF 40/94 reads (43%) | catalogued as COSV100541708, COSV59512997; called by muse, mutect2, varscan2
- SEC14L3 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.166); catalogued as rs115812777; called by muse, mutect2, varscan2
- SH3GL1 | c.889C>T p.R297W | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.332); catalogued as rs149527990; called by muse, mutect2, varscan2
- SH3PXD2B | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.066); catalogued as rs753004133, COSV61129672; called by muse, mutect2, varscan2
- SLC32A1 | c.950A>G p.Y317C | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV54148204; called by muse, mutect2, varscan2
- SLC41A3 | c.1059G>C p.Q353H | Missense Mutation (SNP) | VAF 68/126 reads (54%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.663); catalogued as COSV100259775, COSV59990179; called by muse, mutect2, varscan2
- SLFN13 | c.2156C>G p.S719* | Nonsense Mutation (SNP) | VAF 137/177 reads (77%) | catalogued as COSV53193489, COSV99540058; called by muse, mutect2, varscan2
- SRGAP3 | c.2362G>A p.G788S | Missense Mutation (SNP) | VAF 76/140 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.355); catalogued as rs773096168, COSV64533888; called by muse, mutect2, varscan2
- SYNPO2 | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61116001; called by muse, mutect2, varscan2
- TDRD6 | c.2480G>A p.R827Q | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.961); catalogued as rs1181898264, COSV60178196; called by muse, mutect2, varscan2
- TECPR2 | c.2317G>A p.E773K | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as COSV63973782; called by muse, mutect2, varscan2
- THRB | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs867926730, COSV54979328; called by muse, mutect2, varscan2
- TIGAR | c.541A>G p.N181D | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV51629618; called by muse, mutect2, varscan2
- TRIB3 | c.985C>G p.L329V | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.034); catalogued as COSV53931894, COSV53932474; called by muse, mutect2, varscan2
- TRIR | c.413C>T p.T138M | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as rs935475457, COSV54407573, COSV54407817; called by muse, mutect2, varscan2
- TRMT9B | c.1329G>A p.W443* | Nonsense Mutation (SNP) | VAF 10/17 reads (59%) | catalogued as rs1366170339, COSV101501675; called by muse, mutect2, varscan2
- TUBA3D | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.305); catalogued as COSV58312165; called by muse, mutect2, varscan2
- UGT2B17 | c.1351C>G p.H451D | Missense Mutation (SNP) | VAF 65/180 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58500823, COSV58502470; called by muse, mutect2, varscan2
- UHRF1BP1 | c.1360C>T p.Q454* | Nonsense Mutation (SNP) | VAF 35/83 reads (42%) | catalogued as rs773648455, COSV99512544; called by muse, mutect2, varscan2
- ZC3H7B | c.1631A>G p.K544R | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV60964362; called by muse, mutect2, varscan2
- ZFHX4 | c.1230del p.L411Cfs*4 | Frame Shift Del (DEL) | VAF 19/69 reads (28%) | catalogued as COSV99265992; called by mutect2, pindel, varscan2
- ZFHX4 | c.10586T>A p.I3529N | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.568); catalogued as COSV51492125; called by muse, mutect2, varscan2
- FAM193A | c.2497dup p.M833Nfs*12 | Frame Shift Ins (INS) | VAF 18/57 reads (32%) | called by mutect2, varscan2
- FTL | c.440_465del p.D147Gfs*25 | Frame Shift Del (DEL) | VAF 36/153 reads (24%) | called by mutect2, pindel
- KIF16B | c.476_479dup p.D160Efs*10 | Frame Shift Ins (INS) | VAF 31/87 reads (36%) | called by mutect2, pindel, varscan2
- SENP7 | c.2087del p.K696Sfs*2 | Frame Shift Del (DEL) | VAF 15/91 reads (16%) | called by mutect2, pindel, varscan2
- ALDH1A2 | c.396C>T p.F132= | Silent (SNP) | VAF 39/74 reads (53%) | catalogued as rs372883837; called by muse, mutect2, varscan2
- ARHGEF4 | c.1359C>T p.A453= | Silent (SNP) | VAF 24/87 reads (28%) | catalogued as rs774222755, COSV58129188; called by muse, mutect2, varscan2
- CYP2A6 | c.510C>T p.P170= | Silent (SNP) | VAF 40/109 reads (37%) | catalogued as COSV56536945; called by muse, mutect2, varscan2
- DCAF5 | c.540C>T p.P180= | Silent (SNP) | VAF 42/84 reads (50%) | catalogued as COSV58462726; called by muse, mutect2, varscan2
- DOP1A | c.4377C>T p.L1459= | Silent (SNP) | VAF 45/109 reads (41%) | catalogued as COSV52716813; called by muse, mutect2, varscan2
- DOP1B | c.6738C>T p.F2246= | Silent (SNP) | VAF 39/99 reads (39%) | catalogued as rs1459984521, COSV67690910; called by muse, mutect2, varscan2
- DPYSL5 | c.174G>A p.V58= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV56515676; called by muse, mutect2, varscan2
- FAR2 | c.1008G>A p.R336= | Silent (SNP) | VAF 80/204 reads (39%) | catalogued as rs1393875615, COSV51729245; called by muse, varscan2
- GUCY1A2 | c.603C>T p.N201= | Silent (SNP) | VAF 32/85 reads (38%) | catalogued as rs144052450, COSV56482654; called by muse, mutect2, varscan2
- HEPH | c.2793T>C p.N931= (on ENST00000343002; = p.N664= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/50 reads (80%) | catalogued as COSV57970840; called by muse, mutect2, varscan2
- HRH3 | c.1129C>T p.L377= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as COSV58050193; called by muse, mutect2, varscan2
- IMMT | c.663C>G p.A221= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as COSV99607682; called by muse, varscan2
- KCNV2 | c.1428C>T p.L476= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV66057380; called by muse, varscan2
- MYC | c.576G>T p.S192= (on ENST00000377970; = p.S207= on NM_002467.6) | Silent (SNP) | VAF 25/52 reads (48%) | catalogued as rs751465079, COSV52378049; called by muse, mutect2, varscan2
- MYH15 | c.3039G>A p.E1013= | Silent (SNP) | VAF 21/119 reads (18%) | catalogued as rs1428064960, COSV56318297; called by muse, mutect2, varscan2
- NDC80 | c.1395G>A p.L465= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as rs1262328132, COSV55249549; called by muse, mutect2, varscan2
- NDUFV1 | c.675G>A p.L225= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as COSV59596480; called by muse, mutect2, varscan2
- NPHP4 | c.4038C>T p.V1346= | Silent (SNP) | VAF 26/43 reads (60%) | catalogued as COSV65397382; called by muse, mutect2, varscan2
- NRDE2 | c.3462G>A p.P1154= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs1163207874, COSV62964537; called by muse, mutect2, varscan2
- NRROS | c.396G>A p.P132= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV60747500; called by muse, mutect2, varscan2
- OCA2 | c.78C>T p.S26= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as rs751013587, COSV62356478; called by muse, mutect2, varscan2
- PIGM | c.939C>T p.L313= | Silent (SNP) | VAF 31/91 reads (34%) | catalogued as rs758598643, COSV63636014; called by muse, mutect2, varscan2
- PLA2R1 | c.2916G>C p.L972= | Silent (SNP) | VAF 37/80 reads (46%) | catalogued as COSV51785581; called by muse, mutect2, varscan2
- PLEK2 | c.78C>T p.F26= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV53606717; called by mutect2, varscan2
- POLE | c.1995G>A p.R665= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as COSV57689075; called by muse, mutect2, varscan2
- PRX | c.33G>A p.L11= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV99398106; called by muse, varscan2
- RBFOX1 | c.99G>A p.P33= | Silent (SNP) | VAF 25/124 reads (20%) | catalogued as rs758785440, COSV60952521; called by muse, mutect2, varscan2
- SPACA7 | c.450G>A p.K150= | Silent (SNP) | VAF 27/77 reads (35%) | catalogued as COSV52099857; called by muse, mutect2, varscan2
- SPATA31A1 | c.891C>G p.V297= | Silent (SNP) | VAF 70/348 reads (20%) | called by muse, mutect2, varscan2
- SPEF2 | c.2070A>C p.S690= | Silent (SNP) | VAF 22/43 reads (51%) | catalogued as COSV61552883; called by muse, mutect2, varscan2
- SVEP1 | c.10356G>A p.L3452= | Silent (SNP) | VAF 32/42 reads (76%) | catalogued as COSV52838019, COSV52843256; called by muse, mutect2, varscan2
- TERF2IP | c.6G>T p.A2= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as COSV55614097; called by muse, mutect2, varscan2
- TNPO2 | c.1212C>T p.F404= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as COSV63509898; called by muse, mutect2, varscan2
- TPTE | c.363T>C p.Y121= (on ENST00000618007 / NM_199261.4; = p.Y103= on NM_199259.4) | Silent (SNP) | VAF 19/154 reads (12%) | called by muse, mutect2, varscan2
- ZCCHC14 | c.396A>G p.K132= (on ENST00000268616; = p.K269= on NM_015144.3) | Silent (SNP) | VAF 39/148 reads (26%) | catalogued as COSV51889898; called by muse, mutect2, varscan2
- ZNF479 | c.342A>G p.T114= | Silent (SNP) | VAF 43/119 reads (36%) | catalogued as rs370210526; called by muse, mutect2, varscan2
- ZNF676 | c.450T>C p.Y150= (on ENST00000650058; = p.Y118= on NM_001001411.3) | Silent (SNP) | VAF 51/136 reads (38%) | catalogued as rs765070522, COSV68094699; called by muse, mutect2, varscan2
- TBX1 | c.1009+658C>T | Intron (SNP) | VAF 6/10 reads (60%) | catalogued as rs1303578943, COSV60355164; called by muse, mutect2, varscan2
